Gene-level copy-number profile of tumor specimen CDDP-A8B6-TTP1-C from CDDP_EAGLE case CDDP-A8B6, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74 years.
Specimen CDDP-A8B6-TTP1-C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8b850563-bb11-4f4f-868c-0d2a27681f0a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-A8B6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/6e6cd70a-1661-4f3e-9b7a-fcf712af1894

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 3,412; copy number 2: 30,352; copy number 3: 20,298; copy number 4: 3,058; copy number 5: 973; copy number 6: 69; copy number 7: 1; copy number 8: 47; copy number 9: 448; copy number 10: 6; copy number 11: 62; copy number 13: 38; copy number 18: 1; copy number 19: 43.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:48,403,854–48,440,456, 2 genes (within-gene range 0–1): PLXNB1, CCDC51.
- chr8:7,715,443–8,116,949, 34 genes: FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr13:48,303,744–48,599,436, 6 genes (within-gene range 0–2): RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.
- chr14:18,667,249–18,909,673, 7 genes: CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7.
- chr14:106,257,762–106,324,760, 14 genes (within-gene range 0–3): IGHV3-22, IGHVII-22-1, IGHVIII-22-2, IGHV3-23, IGHV1-24, HOMER2P2, LINC00226, IGHV3-25, IGHVIII-25-1, IGHV2-26, IGHVIII-26-1, IGHVII-26-2, IGHV7-27, IGHV4-28.
- chr16:34,266,041–35,284,146, 26 genes: BCLAF1P2, AC135776.4, LINC02184, AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11, NAMPTP3, VPS35P1, VN1R68P, VN1R69P, AC023824.5, AC023824.6, UBE2MP1, SLC25A1P4, AC023824.1, AC023824.2, AC023824.4, AC023824.3, TP53TG3GP, RARRES2P5, FGFR3P5, FRG2JP, RARRES2P6, AGGF1P8.
- chr17:18,450,244–18,475,920, 4 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr22:38,952,741–38,992,804, 2 genes (within-gene range 0–2): APOBEC3A, APOBEC3B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,688 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:164,670,878–166,862,110, 22 genes, copy number 11: LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1.
- chr3:174,438,573–175,810,548, 5 genes, copy number 10 (within-gene range 3–10): NAALADL2, RN7SKP40, EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2.
- chr3:175,473,919–175,477,602, 1 gene, copy number 10: AC008180.3.
- chr3:175,938,929–176,114,537, 5 genes, copy number 11: AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1.
- chr3:179,323,031–186,922,753, 197 genes, copy number 5 (broad region; genes not listed).
- chr4:47,431,960–47,838,106, 9 genes, copy number 5: AC107398.3, COMMD8, AC107398.4, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1.
- chr7:17,790,761–17,940,501, 1 gene, copy number 5: SNX13.
- chr8:7,355,517–7,385,558, 2 genes, copy number 5: ZNF705G, DEFB108C.
- chr8:60,141,821–60,142,142, 1 gene, copy number 7: SLC2A13P1.
- chr11:60,159,687–62,153,169, 82 genes, copy number 8–19 (broad region; genes not listed).
- chr12:87,041,916–87,042,423, 1 gene, copy number 5: AC079597.1.
- chr14:19,905,917–20,609,884, 52 genes, copy number 5: OR4K4P, AL391156.1, OR4K5, OR4K1, OR4K16P, OR4K15, OR4Q2, OR4K14, OR4K13, OR4U1P, OR4L1, RNA5SP380, OR4T1P, OR4K17, OR4N5, PSMB7P1, GTF2IP22, OR11G1P, OR11G2, OR11H5P, OR11H6, OR11H7, OR11H4, TTC5, AL356019.2, AL356019.1, CCNB1IP1, AL355075.6, SNORA79B, SNORD126, AL355075.4, RPPH1, PARP2, AL355075.1, TEP1, RNA5SP382, KLHL33, AL355075.5, OSGEP, AL355075.2, APEX1, PIP4P1, PNP, AL355075.3, RNASE10, PTCD2P1, SETP1, RNASE9, AL163195.3, RNASE11, AL163195.2, RNASE12.
- chr14:20,768,404–23,560,778, 255 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr19:27,638,483–45,406,349, 729 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr20:31,257,664–39,933,239, 282 genes, copy number 5–13 (broad region; genes not listed).
- chr22:18,873,543–19,527,545, 44 genes, copy number 5: FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH, AC007326.5, AC007326.2, DGCR5, AC007326.3, DGCR5, AC007326.1, AC000095.2, AC000095.1, FAM246C, CA15P1, DGCR2, Y_RNA, DGCR11, AC004461.1, AC004461.2, AC004471.1, AC004471.2, TSSK1A, ESS2, TSSK2, GSC2, LINC01311, SLC25A1, CLTCL1, AC000072.1, AC000081.1, AC000081.2, KRT18P62, HIRA, C22orf39, RN7SL168P, MRPL40, AC000068.1, UFD1, AC000068.3, AC000068.2, CDC45, AC000082.1, CLDN5.

Autosomal genes at a single copy (total copy number 1): 2,821. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
